Surgical pathology report (de-identified scan), TCGA case TCGA-AK-3431, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Fox Chase, specimen TCGA-AK-3431-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Clinical History/Diagnosis: Right renal mass.

Source of Specimen(s):

A: Lipoma

B: Right kidney and right adrenal

C: Portion of Vena CavaThrombus

Gross Description:

Received in three parts.

Source of Tissue: 1. Labeled #1 "lipoma"

Gross Description: The specimen is received fresh in a container labeled with the patient's name designated "lipoma" and consists of a yellow rubbery mass measuring 7.5 x 5 x 4 cm. Sections disclose encapsulated moist glistening adipose tissue. No areas of hemorrhage, cysts or calcifications are noted. Representative sections are submitted in 1A and 1B.

Designation of Sections:

Summary of Sections:

Source of Tissue: 2. Labeled #2 "right kidney and right adrenal"

Gross Description: The specimen is received fresh in a container labeled with the patient's name designated "right kidney and right adrenal" and consists of a radical nephrectomy specimen weighing 1640 gm with an overall measurement of 28 x 17 x 10 cm. There is an appreciable amount of perinephric fat encompassing the specimen. Superiorly in the fat, there is a 5 x 3 x 1.5 cm adrenal gland. The gland is red to orange with no gross lesions or masses found. At the hilum, the ureter measures 10 x 0.5 x 0.5 cm and is patent. The ureter is opened and is grossly free of lesions or masses. The perinephric fat is unable to be removed from the kidney. The kidney is bivalved. The kidney is markedly asymmetrical and distorted due to a large yellowish-tan to orange tumor measuring 11 x 10 x 8 cm. The lesion obliterates the inferior fold and inferior and central calyces. No gross invasion through the capsule is proven. Medial laterally and superiorly, there is some more normal appearing renal parenchyma with well defined corticomedullary gritty junctions. No lymph nodes are found.

Designation of Sections: 2A ureter and vascular margins, 2B tumor in renal pelvic, 2C-2D tumor pushing on renal capsule, 2E-2F grossly viable tumor, 2G uninvolved right superior pole of kidney, 2H fat overlying tumor, 2I adrenal gland, 2J-2L perinephric fat at hilum.

Summary of Sections: A-K

Source of Tissue: 3. Labeled #3, "portion of vena cava thrombus"

[page 2 of 2]
Gross Description: Received fresh with patient identification is a 2.5 x 1.0 x 0.6 cm tan to tan-pink rubbery firm tissue fragment which is entirely submitted in one block.

Designation of Sections: Block 3

Summary of Sections: undesignated-multiple

Final Diagnosis:

1. Soft tissue, subcutaneous right flank (excision):
- Fibroadipose tissue consistent with lipoma.
2. Right kidney and right adrenal gland (right radical nephrectomy):
- Conventional (clear cell) renal adenocarcinoma, Grade 3 (11 cm) limited to the kidney, no capsular invasion, unifocal.
- Ureter and vascular resection margins negative.
- No angiolymphatic invasion identified.
- Diffuse type diabetic nephrosclerosis with arterial nephrosclerosis.
- Adrenal gland uninvolved by tumor.
3. Vena cava thrombus (excision):
- Calcified atherosclerotic plaque and organized thrombus.
- No tumor seen.

Stage: pT2,Nx,Mx.

FC Cytogenetics Tumor

Results-Comments

CYTOGENETIC ANALYSIS REPORTS

DIAGNOSIS: Right Renal Mass

KARYOTYPE: Normal [REDACTED] karyotype: 46,XX[20]

RESULTS: The renal mass was harvested after seven and eleven days in culture. The chromosomes from twenty metaphases were counted and analyzed, and three of these metaphases were karyotyped by G-banding. The modal chromosome number was 46, and the cells appeared to have a normal karyotype. These normal results may reflect an overgrowth of normal interstitial or adjacent tissue rather than tumor.

Source: NCI Genomic Data Commons file ba237bdd-47da-4ee1-b3e0-a3f3741b0d2e (TCGA-AK-3431.B145ECA9-7FE5-4D96-B33A-941069F79461.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).